Surgical pathology report (de-identified scan), TCGA case TCGA-L5-A8NM, project TCGA-ESCA (Esophageal Carcinoma), tissue source site University of Michigan, specimen TCGA-L5-A8NM-01A (Primary Tumor).

[page 1 of 3]
ICD-O-3
Adenocarcinoma NOS 8140/3
Site ^{CHF} Esophagus, distal third C15.5
path gastroesophageal junction C16.0
OKD 1/17/14

ACCESSION:

OPER DATE:

REQ DOC:

PROCEDURE:

VERIFIED BY:

year-old with chest pain and dysphagia. Clinical Diagnosis: Positive adeno
of the CECA, J-tube, esophagoscopy.

PROCEDURE:

1. "Left cervical mass." A 2 x 1.5 x 0.8 cm tan-red soft tissue nodule with glistening lobular tan parenchyma. Bisected.
1A. Frozen section control.
1B. Rest of specimen.
2. "Esophagus." Received in formalin in a large container is a 6.1 cm long, 3.2 cm wide and approximately 0.6 cm deep. Esophagus is attached to a 7 x 4 x 3 cm portion of stomach and attached fibroadipose tissue. The esophageal mucosa is pink to grey and folded. At the gastroesophageal junction is a 2 x 2 cm firm, white-tan, ulcer. This lies 5 cm from the esophageal margin and 2 cm from the gastric margins of resection. The radial margin is inked black. The rest of the gastric mucosa is tan-brown with appropriate rugae. Cut sections reveal a white-tan tumor which abuts the inked black radial margin. At this point, the tumor is 0.7 cm thick. At least two lymph nodes are identified in the paraesophageal fat up to 1.5 x 1.1 x 0.6 cm.
2A through 2E. Tumor and esophagus.
2F. Tumor to stomach.
2G. Gastric margin of resection.
2H. Possible lymph node.
2I & 2J. One bisected lymph node each.
3. "Proximal cervical esophageal margin." Received in formalin in a small container is a 1 cm length of proximal esophagus, 1.5 x 1.5 cm. Surgical staples present.
4. "Paraesophageal lymph node." Received in formalin in a small container is a 0.5 cm tan bit.
5. "Celiac assess lymph node." Received in formalin in a small container is a 1 x 0.8 x 0.5 cm tan-white lymph node.

FROZEN SECTION REPORT:

Hyperplastic thyroid tissue with macro follicles.

[page 2 of 3]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:
NAME:
BIRTHDATE:

PATIENT NBR:

PAGE #: 3
SEX: F
ADM DATE:

ACCESSION:

OPER DATE:

REQ DOC:

I, _____, have reviewed and interpreted the frozen section material at the time it was requested.
Permanent sections confirm frozen section report.

PROCEDURE:

VERIFIED BY:

ESOPHAGEAL, CARDIAC AND GASTROESOPHAGEAL JUNCTION CARCINOMA:

Type of carcinoma: Adenocarcinoma
If adenocarcinoma, it is arising in: GE junction
Depth of invasion: Muscularis propria
Number of positive lymph nodes: 1/5
Extranodal metastasis: Unknown
Pattern of invasion: Expansile
Esophageal and gastric resection margins involved: No
Deep resection margin involved: No
TNM classification: T2 N1 Mx

PROCEDURE:

VERIFIED BY:

- 2 & 3. Esophagus, resection: Adenocarcinoma arising at the GE junction. Surgical margins free. Please see template for details.
4. Paraesophageal soft tissue, excision: Skeletal muscle. No lymph node present.
5. Celiac lymph node, excision: One lymph node negative for metastatic carcinoma.
1. Soft tissue of left cervix, excision: Hyperplastic thyroid tissue.

[page 3 of 3]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:
NAME:
BIRTHDATE:

PATIENT NBR:

PAGE #: 4
SEX: F
ADM DATE:

ACCESSION:

OPER DATE:

REQ DOC:

1. the signing staff pathologist, have personally examined and interpreted the slides from this case.

Code:

** END OF PREVIOUS DIAGNOSIS INQUIRY **

Source: NCI Genomic Data Commons file 0758c905-3ed2-4550-858a-69b1ab6d77d3 (TCGA-L5-A8NM.BE7411CD-1437-495B-86B0-9FE32E329C31.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).